Gene-level copy-number profile of tumor specimen TCGA-13-0897-01A from TCGA case TCGA-13-0897, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 54.5 years (19,894 days).
Specimen TCGA-13-0897-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.00f502c5-55b4-4a1b-987e-263ef1b9c3d6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0897-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/60b5a91d-ddf9-4bd5-8d19-98b09c5e9988

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,581; copy number 2: 34,634; copy number 3: 7,371; copy number 4: 1,420; copy number 5: 479; copy number 6: 334.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0897-01A-01D-0399-01): tumor purity 0.81, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 813 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:112,140,898–112,649,530, 12 genes, copy number 5 (within-gene range 3–5): SLC9C1, AC128688.1, AC112487.1, AC112487.2, CD200, AC092894.1, BTLA, OR7E100P, AC092692.1, ATG3, SLC35A5, CCDC80.
- chr8:94,879,770–145,066,685, 801 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,336. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
